Gene-level copy-number profile of tumor specimen C3L-07963-01 from CPTAC case C3L-07963, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.7 years (24,372 days).
Specimen C3L-07963-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file afa644cc-8d23-47b3-a1b9-91682b72a36e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07963-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/23c48d7e-b20a-4ead-bc35-a755f3cf2991

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 648; copy number 1: 338; copy number 2: 11,004; copy number 3: 34,974; copy number 4: 10,040; copy number 5: 622; copy number 6: 778; copy number 7: 52; copy number 8: 44; copy number 9: 45; copy number 12: 4; copy number 14: 105; copy number 15: 17; copy number 16: 12; copy number 17: 2; copy number 18: 14; copy number 20: 9; copy number 21: 9; copy number 22: 13; copy number 23: 32; copy number 24: 13; copy number 26: 19; copy number 27: 13; copy number 28: 8; copy number 30: 3; copy number 32: 67; copy number 37: 1; copy number 40: 6; copy number 41: 17.

Homozygous deletions (total copy number 0; autosomes only): 136 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,038,160–21,543,329, 136 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 505 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:63,652,675–64,103,131, 15 genes, copy number 8 (within-gene range 4–8): SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994.
- chr3:64,099,273–64,101,122, 1 gene, copy number 8 (within-gene range 4–8): PRICKLE2-AS1.
- chr6:56,056,590–56,433,213, 4 genes, copy number 7: COL21A1, DHFRP6, AL031779.1, RCC2P7.
- chr6:106,695,535–107,824,317, 15 genes, copy number 8–24: LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4.
- chr6:108,041,409–108,837,113, 24 genes, copy number 8–15: OSTM1, Y_RNA, OSTM1-AS1, NR2E1, AL078596.1, SNX3, Z98742.2, RNA5SP212, Z98742.1, RNU6-1144P, AFG1L, Z98742.3, AL356121.2, AL356121.1, AL353706.1, RNU6-770P, AL139106.1, AL391646.1, FOXO3, SUMO2P8, LINC00222, ZNF259P1, Z95118.2, Z95118.1.
- chr6:109,095,110–109,506,800, 13 genes, copy number 8 (within-gene range 4–8): CEP57L1, CCDC162P, AL359711.1, PTCHD3P3, RNY3P11, RPL7P28, CD164, AL359711.2, PPIL6, SMPD2, MICAL1, ZBTB24, AL109947.1.
- chr6:110,180,141–110,358,272, 3 genes, copy number 12: CDC40, METTL24, AL050350.1.
- chr7:96,858,182–97,599,260, 13 genes, copy number 8–37: MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1, AP1S2P1, RN7SKP104.
- chr7:98,106,862–102,283,958, 162 genes, copy number 7–14 (within-gene range 2–14) (broad region; genes not listed).
- chr12:14,356,842–27,824,382, 215 genes, copy number 16–41 (broad region; genes not listed).
- chr12:43,054,089–46,004,685, 37 genes, copy number 7: MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1.
- chr12:72,727,923–73,208,317, 3 genes, copy number 12–17 (within-gene range 2–17): AC133480.1, AC090503.2, LINC02444.

Autosomal genes at a single copy (total copy number 1): 338. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
